Somatic mutation profile of tumor specimen MMRF_2269_1_BM_CD138pos (aliquot MMRF_2269_1_BM_CD138pos_T1_KHS5U_K14064) from MMRF case MMRF_2269, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.9 years (25,162 days).
Specimen MMRF_2269_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfa8c639-82b3-45b4-8a84-415eaa6c87b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2269_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2269_1_PB_Whole_C2_KHS5U_K14063; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bafcd30a-aa2f-4df0-a727-aa2044a2aed3

The open-access MAF lists 91 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 21, Silent 12, Intron 9, 5'UTR 4, RNA 3, Nonsense Mutation 2, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- DISP3 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248807960, COSV99609506; called by muse, mutect2, varscan2
- EPHB1 | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 76/172 reads (44%) | catalogued as COSV101213243; called by muse, mutect2, varscan2
- FILIP1 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766903756, COSV52737380; called by muse, mutect2, varscan2
- GIN1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV67537106; called by muse, mutect2, varscan2
- H1-4 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799905, COSV56803909; called by muse, mutect2, varscan2
- IGHV5-51 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.747); catalogued as rs532191081; called by muse, varscan2
- LGSN | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs867230083; called by muse, mutect2, varscan2
- MPDZ | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs769011115; called by muse, mutect2
- OPLAH | c.1363A>G p.M455V | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as rs782121351; called by muse, mutect2, varscan2
- OR4K1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 95/303 reads (31%) | catalogued as rs145757525; called by muse, mutect2, varscan2
- PCDH15 | c.3415A>C p.N1139H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs757791232; called by muse, mutect2, varscan2
- RSPH14 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs775850631, COSV53268318; called by muse, mutect2, varscan2
- RYR1 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as rs1169294876, COSV100614822, COSV62113655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF4 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV100610040; called by muse, mutect2
- TSC2 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 123/127 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487642536, COSV99555525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF112 | c.2132A>G p.H711R (on ENST00000337401 / NM_001083335.2; = p.H705R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100495462; called by muse, mutect2, varscan2
- ALPP | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ATP10A | c.3641C>A p.T1214N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CAD | c.2450T>G p.L817W | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CELF5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 149/270 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CSGALNACT1 | c.1272dup p.M425Dfs*16 | Frame Shift Ins (INS) | VAF 41/76 reads (54%) | called by mutect2, pindel, varscan2
- DOCK6 | c.5361+5G>A | Splice Region (SNP) | VAF 89/192 reads (46%) | called by muse, mutect2, varscan2
- DSCAML1 | c.412G>A p.A138T (on ENST00000321322; = p.A78T on NM_020693.4) | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FLRT3 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 188/192 reads (98%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GMIP | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 148/298 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA13 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 37/454 reads (8%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.932); called by muse, mutect2
- IGKJ4 | c.9_14dup p.G5_G6dup | In Frame Ins (INS) | VAF 29/92 reads (32%) | called by mutect2, pindel, varscan2
- IGLV3-1 | c.234_236delinsCC p.E78Dfs*14 | Frame Shift Del (DEL) | VAF 53/183 reads (29%) | called by pindel, varscan2*
- LATS2 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAF | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 61/64 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCPH1 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SH3RF1 | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SMC5 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SPAG4 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TMED6 | c.344T>G p.F115C | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- WASF3 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZCRB1 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF292 | c.5072_5075del p.N1691Mfs*8 | Frame Shift Del (DEL) | VAF 38/42 reads (90%) | called by mutect2, pindel, varscan2
- ZNF783 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZP2 | c.1008A>T p.L336F | Missense Mutation (SNP) | VAF 152/219 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADGRL4 | c.993C>T p.V331= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV66061777; called by muse, mutect2, varscan2
- ATXN7L2 | c.546A>G p.K182= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV63992309; called by muse, mutect2, varscan2
- DMXL2 | c.7434T>C p.D2478= | Silent (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- HNRNPH3 | c.135G>A p.G45= | Silent (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- IL1R2 | c.1035C>A p.S345= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- MAP3K14 | c.159A>T p.G53= | Silent (SNP) | VAF 122/319 reads (38%) | catalogued as COSV60923851; called by muse, mutect2, varscan2
- PARN | c.711A>G p.R237= | Silent (SNP) | VAF 499/765 reads (65%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.828C>T p.P276= | Silent (SNP) | VAF 102/203 reads (50%) | catalogued as COSV54020338; called by muse, mutect2, varscan2
- SAFB | c.1896C>T p.R632= | Silent (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- SLC44A1 | c.1881A>G p.E627= | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- SLC4A3 | c.3153C>T p.V1051= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs777006500; called by muse, mutect2, varscan2
- SMARCC2 | c.867G>A p.R289= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- AHR | c.*2496T>C | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- ALDH9A1 | c.*302T>A | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.317+18A>G | Intron (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- CIB2 | c.-67C>G | 5'UTR (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- EFCAB14 | c.*2175T>G | 3'UTR (SNP) | VAF 66/128 reads (52%) | called by muse, mutect2, varscan2
- EREG | c.-82C>T | 5'UTR (SNP) | VAF 38/74 reads (51%) | catalogued as rs1034181924; called by muse, mutect2, varscan2
- EYA1 | c.34-47917T>A | Intron (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- FAM216B | c.*923dup | 3'UTR (INS) | VAF 14/35 reads (40%) | called by mutect2, varscan2
- FGF13 | c.*605C>A | 3'UTR (SNP) | VAF 44/44 reads (100%) | called by muse, mutect2, varscan2
- HOXD3 | c.*668G>A | 3'UTR (SNP) | VAF 5/90 reads (6%) | catalogued as rs1216279734; called by muse, mutect2
- KCNK1 | c.*888C>G | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109965036 G>A | 3'Flank (SNP) | VAF 36/74 reads (49%) | catalogued as COSV52085876; called by muse, mutect2, varscan2
- KIRREL1 | c.*1968C>T | 3'UTR (SNP) | VAF 14/180 reads (8%) | catalogued as rs1368140554; called by muse, mutect2
- LAS1L | c.-46A>C | 5'UTR (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- LGI4 | c.628+131T>C | Intron (SNP) | VAF 56/108 reads (52%) | catalogued as rs903001867; called by muse, mutect2, varscan2
- LINC01561 | n.827C>T | RNA (SNP) | VAF 15/54 reads (28%) | catalogued as rs956456207; called by muse, mutect2, varscan2
- LRRC57 | c.-326G>C | 5'UTR (SNP) | VAF 16/27 reads (59%) | catalogued as rs991235111; called by muse, mutect2, varscan2
- MCRIP1 | c.-48-117G>A | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2
- MPP2 | c.*1555G>A | 3'UTR (SNP) | VAF 66/140 reads (47%) | called by muse, mutect2, varscan2
- OSBPL6 | c.*775A>G | 3'UTR (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- OTUD5 | c.688+3835T>C | Intron (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- PABPC5 | c.*1225C>A | 3'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- PCDH17 | c.*77C>A | 3'UTR (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- PDGFRB | c.*1688A>G | 3'UTR (SNP) | VAF 55/76 reads (72%) | called by muse, mutect2, varscan2
- PHF20L1 | c.*1500C>T | 3'UTR (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99621257; called by muse, mutect2, varscan2
- PIK3R2 | c.*891G>A | 3'UTR (SNP) | VAF 34/84 reads (40%) | called by muse, varscan2
- PTPN6 | c.326+70G>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2030-28A>G | Intron (SNP) | VAF 138/313 reads (44%) | catalogued as rs756584488; called by muse, mutect2, varscan2
- SLC7A13 | c.*120dup | 3'UTR (INS) | VAF 54/119 reads (45%) | called by mutect2, varscan2
- SPRYD7 | c.*850A>G | 3'UTR (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- ST3GAL1 | c.*3799A>G | 3'UTR (SNP) | VAF 82/188 reads (44%) | called by muse, mutect2, varscan2
- TCP1P3 | n.1463G>A | RNA (SNP) | VAF 9/190 reads (5%) | catalogued as rs915386171; called by muse, mutect2
- TMF1 | c.*1187C>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- TUBA1B | c.3+177A>T | Intron (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2
- UBBP4 | n.1446G>C | RNA (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- UBL3 | c.*2050T>A | 3'UTR (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- UBL3 | c.*1797A>G | 3'UTR (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- USP4 | c.696-320C>T | Intron (SNP) | VAF 104/210 reads (50%) | called by muse, mutect2, varscan2
